Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6304, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6304-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. STOMACH, TRANSVERSE COLON, RIGHT COLON, TERMINAL ILEUM, PORTION OF SMALL INTEST
- B. GASTRIC SUTURE LINE

DIAGNOSIS:

- A. TERMINAL ILEUM, RIGHT COLON, TRANSVERSE COLON, OMENTUM, MID JEJUNUM, GREATER CURVATURE OF STOMACH, AND ABDOMINAL WALL, EN BLOC RESECTION:
- INVASIVE POORLY DIFFERENTIATED ADENOCARCINOMA INVOLVING PERICOLIC FAT AND GASTRIC MUSCULARIS PROPRIA AND SPARING GASTRIC MUCOSA
- ADJACENT ACUTE SUPPURATIVE AND CHRONIC INFLAMMATION WITH ABSCESS FORMATION INVOLVING ADHERED SEGMENT OF SMALL INTESTINE WITH INTESTINAL PERFORATION, ABDOMINAL WALL SKELETAL MUSCLE, AND SUBCUTANEOUS ADIPOSE TISSUE (ALL NEGATIVE FOR CARCINOMA)
- INVASIVE CARCINOMA SIZE 4.5 X 4.5 CM
- FOCAL SQUAMOUS DIFFERENTIATION PRESENT
- NO TUMOR SEEN IN TWENTY FIVE LYMPH NODES (0/25)
- MARGINS NEGATIVE FOR CARCINOMA
- GASTRIC MUCOSA WITH FOCAL CHRONIC GASTRITIS
- ACUTE SEROSITIS
- SEE TEMPLATE
- B. GASTRIC SUTURE LINE, EXCISION:
- GASTRIC MUCOSA, NO TUMOR SEEN

COLORECTAL CANCER TEMPLATE

SPECIMEN TYPE: En bloc resection of terminal ileum, right colon, transverse colon, mid jejunum, greater curvature of stomach, and abdominal wall

TUMOR SITE: Transverse colon

TUMOR CONFIGURATION: Infiltrative and ulcerating

TUMOR SIZE: 4.5 x 4.5 cm

HISTOLOGIC TYPE: Adenocarcinoma

HISTOLOGIC GRADE: G3

EXTENT OF INVASION: Adjacent structures

MARGINS: Negative for carcinoma (proximal, distal, and radial)

LYMPHOVASCULAR INVASION: No definite invasion seen

PERINEURAL INVASION: No definite invasion seen

ADDITIONAL PATHOLOGIC FINDINGS: Abscess formation and dense adhesions

EXTENT OF RESECTION: R0

LYMPH NODES: Negative (0/25)

PATHOLOGIC STAGE: pT4 N0 Mx

[page 2 of 2]
SPECIMEN(S):

A. STOMACH, TRANSVERSE COLON, RIGHT COLON, TERMINAL ILEUM, PORTION OF SMALL INTESTINE
B. GASTRIC SUTURE LINE

CLINICAL HISTORY:

Colon carcinoma

GROSS DESCRIPTION:

A. STOMACH, TRANSVERSE COLON, RIGHT COLON, TERMINAL ILEUM, PORTION OF SMALL INTESTINE

Received fresh is a specimen consisting of segment of terminal ileum (3.0 x 3.0 cm), ascending colon with transverse colon (27 x 8 cm), a portion of distal stomach (7.0 x 4.5 cm) and a segment of small bowel (6 x 4 cm) with segment of omentum measuring 22 x 4 cm. The proximal ileal and distal colonic resection margins measure 3.0 cm and 7.0 cm in circumference. An ellipse of skin measuring 16 x 3.5 cm is also seen. Altogether, the specimen is en bloc resection of transverse colon carcinoma that invades the gastric wall (the mucosa is grossly negative for tumor) and associated with adjacent cavity and abscess formation and induration that involves subcutaneous adipose tissue and abdominal wall muscle, and penetrates the adhered segment of small intestine; the latter has mucosal defect corresponding to this process. The colonic tumor itself measures 4.5 x 4.5 cm (located 5 cm from distal margin) and the associated cavity 4.0 x 4.0 cm. Appendix could not be identified. Multiple lymph nodes are seen (the largest measures 0.7 cm), they are grossly negative for tumor. Representative sections are submitted in:

- A1: proximal ileal margin
- A2: distal colonic margin
- A3: small bowel margin
- A4: gastric margin
- A5-A8: tumor
- A9: stomach with tumor
- A10: Small intestine lesion
- A11: skin with subcutaneous tissue
- A12: cavity with fat
- A13: random colonic mucosa
- A14-A23: possible lymph nodes (A20 has bisected lymph node)
- A24-A27: additional sections of the cavity
- A28-A33: lymph nodes

B. GASTRIC SUTURE LINE

Received in formalin is a 12.0 x 0.7 cm mucosa tissue with staples. Representative tissue is submitted in one cassette.

Source: NCI Genomic Data Commons file 10283e99-dde8-4d5e-9cda-54e8b08bfccf (TCGA-G4-6304.0E039EE7-40EB-4B0F-9A26-462F68940E85.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).